CPTAC case C3N-03007 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ab0750f5-2589-4ec3-a1f0-841eb456dec9

Demographics
Sex at birth: male; Race: white; Year of birth: 1958; Vital status: Dead; Days to death: 58 days; Year of death: 2017; Cause of death: Not Cancer Related; Country of birth: Poland.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Age at diagnosis: 59.6 years (21,772 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T2; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G2; Residual disease: R1; Last known disease status: Tumor free; Days to last known disease status: 58 days; Progression or recurrence: no; Days to last follow up: 58 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.8 cm; Lymph node involvement: Positive; Lymph nodes positive: 12; Lymph nodes tested: 47; Lymphatic invasion present: Yes; Margin status: Uninvolved; Perineural invasion present: Yes; Vascular invasion present: Yes.

Follow-up (1 entry)
- Days to follow up: 58 days; Disease response: Tumor Free; Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 63 kg; Height: 167 cm; BMI: 22.

Exposures
- Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03007-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 22 days; Initial weight: 182 mg; Time between excision and freezing: 5 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03007-22: Section location: Head; Percent tumor nuclei: 30; Percent necrosis: 0.
- Sample C3N-03007-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 22 days; Method of sample procurement: Blood Draw.
